Somatic mutation profile of tumor specimen TCGA-06-0219-01A (aliquot TCGA-06-0219-01A-01D-1491-08) from TCGA case TCGA-06-0219, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,488 days).
Specimen TCGA-06-0219-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1239b29-e4b5-41c3-972f-8faccdf76962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0219-10A (Blood Derived Normal), aliquot TCGA-06-0219-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5f3be64-9d6f-46f4-8bcc-fbf79828d223

The open-access MAF lists 41 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 30, Silent 5, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.6436C>T p.R2146W | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1380838784, COSV58128723; called by muse, mutect2, varscan2
- ACAD10 | c.1910G>C p.S637T | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58154267; called by muse, mutect2, varscan2
- ATCAY | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs199529579; called by muse, mutect2, varscan2
- CDC42EP4 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV59963999, COSV59964441; called by muse, mutect2
- CLCN2 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325778309, COSV55599415; called by muse, mutect2, varscan2
- CNBD2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs750702259, COSV62586269; called by muse, mutect2, varscan2
- COL11A2 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59501876; called by muse, mutect2
- CSMD3 | c.10267G>A p.V3423I (on ENST00000297405 / NM_001363185.1; = p.V3254I on NM_052900.3) | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs376616443; called by muse, mutect2, varscan2
- CYLC2 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66336277; called by muse, mutect2, varscan2
- EPB41L3 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 15/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59455633, COSV59465554; called by muse, mutect2
- ESRRB | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as COSV55058989; called by muse, mutect2, varscan2
- FER1L6 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as rs553419499, COSV67548308; called by muse, mutect2, varscan2
- GLT8D2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs777460443, COSV62560950; called by muse, mutect2, varscan2
- HS1BP3 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 84/294 reads (29%) | catalogued as COSV58312056; called by muse, mutect2, varscan2
- KCNJ8 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1286367742, COSV53715352; called by muse, mutect2, varscan2
- KCNS2 | c.1229T>C p.F410S | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54637438; called by muse, mutect2, varscan2
- KMT2B | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs748861506, COSV55857669, COSV55866786; called by muse, mutect2, varscan2
- LPP | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 58/177 reads (33%) | catalogued as COSV57080266, COSV57119293; called by muse, mutect2, varscan2
- MMS22L | c.1119+2T>G p.X373_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as rs1169514274, COSV51525684; called by muse, mutect2
- NTN4 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs974909872, COSV59217471; called by muse, mutect2, varscan2
- NUFIP1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64790567; called by muse, mutect2, varscan2
- OPRK1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1162961106, COSV55568576; called by muse, mutect2, varscan2
- OR51D1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374266379; called by muse, mutect2, varscan2
- PCDHGA2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1372268024, COSV53905206; called by muse, mutect2, varscan2
- PRDM9 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs775272924, COSV57012158; called by muse, varscan2
- RBMXL2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV60978691; called by muse, mutect2, varscan2
- RPL15 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV57139937; called by muse, mutect2, varscan2
- SLC17A6 | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54133783; called by muse, mutect2, varscan2
- SLC4A10 | c.2236T>C p.F746L (on ENST00000446997 / NM_001354461.2; = p.F716L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55765970; called by muse, mutect2, varscan2
- TRAT1 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV55467430; called by muse, mutect2, varscan2
- TRIM23 | c.1655T>C p.M552T | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs150920611; called by muse, mutect2, varscan2
- TSGA13 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs571780213, COSV63018295; called by muse, mutect2, varscan2
- ZNF518B | c.2642C>A p.S881Y | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58721478; called by muse, mutect2, varscan2
- ZNF536 | c.1434C>G p.H478Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV62819238; called by muse, mutect2, varscan2
- ZNF672 | c.977T>G p.L326R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60637310; called by muse, mutect2, varscan2
- FGD5 | c.3264+1del | Frame Shift Del (DEL) | VAF 48/193 reads (25%) | called by mutect2, pindel, varscan2
- FRMD3 | c.855A>G p.A285= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs374785876; called by muse, mutect2, varscan2
- LIPK | c.783T>C p.T261= | Silent (SNP) | VAF 81/175 reads (46%) | catalogued as COSV68200660; called by muse, mutect2, varscan2
- OR2M4 | c.81T>C p.L27= | Silent (SNP) | VAF 89/276 reads (32%) | catalogued as COSV60707359; called by muse, mutect2, varscan2
- SLCO6A1 | c.111A>G p.G37= | Silent (SNP) | VAF 122/402 reads (30%) | catalogued as rs1007651130, COSV101134338, COSV65806059; called by muse, varscan2
- UROC1 | c.120G>A p.E40= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1159596051, COSV52030207, COSV99332101; called by muse, mutect2, varscan2
